Somatic mutation profile of tumor specimen TCGA-22-4595-01A (aliquot TCGA-22-4595-01A-01D-1267-08) from TCGA case TCGA-22-4595, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 57.9 years (21,146 days).
Specimen TCGA-22-4595-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45e8d99a-4e39-4b2f-ab3f-15f88fe7f88e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4595-11A (Solid Tissue Normal), aliquot TCGA-22-4595-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85cb7f84-402e-41d7-8a93-7044655db7e5

The open-access MAF lists 346 somatic variants for this specimen: 259 protein-altering or splice-affecting, 80 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 223, Silent 80, Nonsense Mutation 11, Frame Shift Del 11, Splice Site 7, Intron 4, Frame Shift Ins 2, RNA 2, In Frame Del 2, Splice Region 2, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B2M | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1057519877, COSV62562849, COSV62563168, COSV62564729; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 43/130 reads (33%) | catalogued as rs1566223700, COSV66454222; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LDLR | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs137943601, CM045057, CM920451; ClinVar: likely benign / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 45/151 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC5 | c.3940C>A p.Q1314K | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV55590384; called by muse, mutect2
- ABCC9 | c.3994G>T p.V1332F | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53972453, COSV53973199; called by muse, mutect2, varscan2
- ABR | c.2095G>A p.D699N (on ENST00000302538 / NM_021962.5; = p.D662N on NM_001092.5) | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.658); catalogued as rs750354403, COSV52145875; called by muse, mutect2, varscan2
- AC131160.1 | c.946A>C p.I316L | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV57700757; called by muse, mutect2, varscan2
- ACSF2 | c.1476-2A>T p.X492_splice | Splice Site (SNP) | VAF 153/324 reads (47%) | catalogued as COSV51972513; called by muse, mutect2, varscan2
- ACSM2A | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54584896, COSV99524839; called by muse, mutect2, varscan2
- ADAMTS4 | c.1941C>G p.D647E | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV63490043, COSV63491387; called by muse, mutect2, varscan2
- ADARB2 | c.1822C>T p.Q608* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV67182212; called by muse, mutect2, varscan2
- ADCY1 | c.1557G>C p.K519N | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV52034904; called by muse, mutect2, varscan2
- ADCY8 | c.3581C>G p.A1194G | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.758); catalogued as rs773491638, COSV53897305, COSV53908386; called by muse, mutect2, varscan2
- AMZ1 | c.956A>C p.Y319S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as COSV56686943; called by muse, mutect2, varscan2
- ANKRD12 | c.2483_2487del p.I828Rfs*5 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs777905119; called by mutect2, pindel, varscan2
- ANO8 | c.2686C>T p.R896C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as rs764862861, COSV50178373; called by muse, mutect2, varscan2
- AREG | c.369A>T p.K123N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs1230584665; called by muse, mutect2, varscan2
- ARMCX6 | c.285C>A p.N95K | Missense Mutation (SNP) | VAF 112/275 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV62680755; called by muse, mutect2, varscan2
- ASB4 | c.1210A>T p.I404F | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57945398; called by muse, mutect2, varscan2
- ASIC5 | c.1123G>T p.V375F | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV73332742; called by muse, mutect2, varscan2
- ASXL2 | c.3242C>T p.S1081L | Missense Mutation (SNP) | VAF 96/451 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV55459122; called by muse, mutect2, varscan2
- ATF7IP | c.2614G>C p.V872L | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV53771125; called by muse, mutect2, varscan2
- ATP13A1 | c.2331G>C p.E777D | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV52286032; called by muse, mutect2, varscan2
- ATP6V1C1 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV67778058; called by muse, mutect2, varscan2
- AXDND1 | c.1137T>A p.Y379* | Nonsense Mutation (SNP) | VAF 57/213 reads (27%) | catalogued as COSV62642919; called by muse, mutect2, varscan2
- BAMBI | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV65003030; called by muse, mutect2, varscan2
- BCAS3 | c.528G>C p.E176D | Missense Mutation (SNP) | VAF 95/189 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as COSV66774391; called by muse, mutect2, varscan2
- BEX1 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 286/618 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV65580078, COSV65580175; called by muse, mutect2, varscan2
- BMP3 | c.1042A>T p.T348S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV51084999; called by muse, mutect2, varscan2
- BRINP1 | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.775); catalogued as COSV56300327; called by muse, mutect2, varscan2
- C12orf40 | c.185del p.C62Sfs*9 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | catalogued as COSV100210158, COSV61131252; called by mutect2, pindel, varscan2
- C2orf76 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 35/144 reads (24%) | catalogued as rs757241576, COSV58346689; called by muse, mutect2, varscan2
- CACNA1A | c.5846C>T p.T1949I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as COSV64198613; called by muse, varscan2
- CASP4 | c.790G>T p.G264W | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376996510; called by muse, mutect2, varscan2
- CASR | c.2441G>C p.R814P (on ENST00000490131; = p.R891P on NM_000388.4) | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.919); catalogued as COSV56136151, COSV56137630, COSV99949441; called by muse, mutect2
- CCDC110 | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.44); catalogued as COSV56871242; called by muse, mutect2, varscan2
- CCDC158 | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 28/140 reads (20%) | catalogued as COSV66356039; called by muse, mutect2, varscan2
- CCDC190 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV63362911; called by muse, mutect2, varscan2
- CCDC39 | c.1229A>G p.Q410R | Missense Mutation (SNP) | VAF 50/335 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as rs376852194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC93 | c.1728G>T p.K576N | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60121412; called by muse, mutect2, varscan2
- CDH9 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50289290; called by muse, mutect2, varscan2
- CDK5RAP2 | c.129G>A p.L43= | Splice Region (SNP) | VAF 90/417 reads (22%) | catalogued as COSV62574426; called by muse, mutect2, varscan2
- CELA2A | c.206T>A p.L69Q | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62747540; called by muse, mutect2, varscan2
- CFAP206 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51534353; called by muse, mutect2, varscan2
- CFAP61 | c.3314G>T p.R1105M | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV55630111; called by muse, mutect2, varscan2
- CHL1 | c.2321C>G p.T774R (on ENST00000397491 / NM_001253387.1; = p.T790R on NM_006614.4) | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV56593842; called by muse, mutect2, varscan2
- CHST6 | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV60000188; called by muse, mutect2, varscan2
- CIP2A | c.2610G>T p.L870F | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV55418802; called by muse, mutect2, varscan2
- CLEC4C | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 101/647 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV63582305, COSV63582674; called by muse, mutect2, varscan2
- CLEC6A | c.492G>C p.W164C | Missense Mutation (SNP) | VAF 76/256 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65987978; called by mutect2, varscan2
- CLVS1 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 95/482 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57975164; called by muse, mutect2, varscan2
- COL11A2 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as COSV59497201; called by muse, mutect2, varscan2
- COPG1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 81/305 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762888021, COSV59112529; called by muse, mutect2, varscan2
- CORO6 | c.729G>C p.Q243H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV61470909; called by muse, mutect2, varscan2
- CREM | c.86A>T p.Q29L | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV61317093; called by muse, mutect2, varscan2
- CRP | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54813527, COSV54814439; called by muse, mutect2, varscan2
- DCAF8 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 57/245 reads (23%) | catalogued as COSV58783859; called by muse, mutect2, varscan2
- DDX3X | c.391G>A p.D131N (on ENST00000399959; = p.D132N on NM_001356.5) | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.877); catalogued as COSV67863614; called by muse, mutect2, varscan2
- DDX3Y | c.244G>C p.G82R | Missense Mutation (SNP) | VAF 101/220 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60176912; called by muse, mutect2, varscan2
- DGKE | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV52349873; called by muse, mutect2, varscan2
- DGKI | c.1909G>T p.G637C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55951077; called by muse, mutect2, varscan2
- DGKZ | c.1621G>A p.G541R (on ENST00000454345 / NM_001105540.2; = p.G353R on NM_003646.4) | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771956773, COSV100552143, COSV58988416; called by muse, mutect2, varscan2
- DHCR7 | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.155); catalogued as COSV62795237; called by muse, mutect2, varscan2
- DNAH3 | c.2582C>A p.A861D | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.079); catalogued as COSV54523171; called by muse, mutect2, varscan2
- DNAH8 | c.4815G>T p.Q1605H | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59446970; called by muse, mutect2, varscan2
- DNAH9 | c.10662C>A p.H3554Q | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.393); catalogued as COSV52350419; called by muse, mutect2, varscan2
- DOCK2 | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 157/306 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56959587; called by muse, mutect2, varscan2
- DPP6 | c.1995C>A p.S665R (on ENST00000377770 / NM_001364500.2; = p.S603R on NM_001936.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV59614400, COSV59626248; called by muse, mutect2, varscan2
- DSG1 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV57135449; called by muse, mutect2, varscan2
- EFCAB6 | c.2647C>T p.L883F | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs369786858; called by muse, mutect2, varscan2
- EIF5 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as rs779336285, COSV53685257, COSV53686672; called by muse, mutect2, varscan2
- EP300 | c.6375C>A p.H2125Q | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV54333040; called by muse, mutect2, varscan2
- EPHA3 | c.2408C>T p.S803L | Missense Mutation (SNP) | VAF 95/414 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760079016, COSV60706606; called by muse, mutect2, varscan2
- EPHB1 | c.2333A>T p.Y778F | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV67661949; called by muse, mutect2, varscan2
- ESRP1 | c.1522T>C p.C508R | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.516); catalogued as COSV64409904; called by muse, mutect2, varscan2
- EXOSC9 | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54666059; called by muse, mutect2
- EXPH5 | c.3665G>T p.R1222L | Missense Mutation (SNP) | VAF 66/362 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV56201810, COSV56202571; called by muse, mutect2, varscan2
- FAT3 | c.11972T>C p.L3991P | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53113117; called by muse, mutect2, varscan2
- FBXO10 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs529842963, COSV52833061; called by muse, mutect2, varscan2
- FDFT1 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 96/402 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.196); catalogued as rs1448891084, COSV55042437; called by muse, mutect2, varscan2
- FNIP2 | c.1348C>G p.P450A | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52439991, COSV52441699; called by muse, mutect2, varscan2
- FRMPD2 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV59718198; called by muse, mutect2, varscan2
- GABRB1 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 93/430 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54982202; called by muse, varscan2
- GALNT17 | c.600G>T p.K200N | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61163094; called by muse, mutect2, varscan2
- GATA3 | c.1104G>A p.M368I | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.364); catalogued as rs1218538798, COSV60518708; called by muse, mutect2, varscan2
- GFOD1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.57); catalogued as rs201398685, COSV64954731; called by muse, mutect2, varscan2
- GPR174 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM136726, COSV52131845; called by muse, mutect2, varscan2
- GPR174 | c.951A>T p.K317N | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs776169203, COSV52132601, COSV99337948; called by muse, mutect2, varscan2
- GRIA3 | c.177C>G p.N59K | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52060583; called by muse, mutect2, varscan2
- GSK3A | c.809T>G p.L270W | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55899385; called by muse, mutect2, varscan2
- GYG2 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as COSV58550263; called by muse, mutect2
- HDLBP | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV60495910; called by muse, mutect2, varscan2
- HEG1 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV60762369; called by muse, mutect2, varscan2
- HHIP | c.1700G>C p.S567T | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.877); catalogued as COSV56839824; called by muse, mutect2, varscan2
- HINFP | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as COSV63432040; called by muse, mutect2, varscan2
- HMCN1 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54901764; called by muse, mutect2, varscan2
- HSPB7 | c.370C>G p.H124D | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61308018; called by muse, mutect2, varscan2
- HTR3D | c.1245G>T p.K415N (on ENST00000382489 / NM_001163646.2; = p.K240N on NM_182537.3) | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as COSV61914168, COSV61915816; called by muse, mutect2, varscan2
- IGHV3-21 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 128/784 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); catalogued as rs562425365; called by muse, varscan2
- IGKV1-6 | c.297C>A p.S99R | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs746073147; called by muse, mutect2, varscan2
- INO80 | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62738340; called by muse, mutect2, varscan2
- INPP5J | c.2048T>C p.L683P (on ENST00000331075 / NM_001284285.2; = p.L315P on NM_001002837.2) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58513153; called by muse, varscan2
- INSIG2 | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 56/355 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV55522581; called by muse, mutect2, varscan2
- IQCB1 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60437588; called by muse, mutect2, varscan2
- ISX | c.5G>T p.C2F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV58086301; called by muse, mutect2, varscan2
- ITIH3 | c.107C>G p.P36R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs771419128, COSV56255201, COSV99835430; called by muse, mutect2, varscan2
- ITM2A | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1423403546, COSV64811043; called by muse, mutect2, varscan2
- KCMF1 | c.427G>C p.D143H | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV69053807; called by muse, mutect2, varscan2
- KCNK5 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 123/495 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63988923, COSV63989342; called by muse, mutect2, varscan2
- KCNQ3 | c.2506G>T p.G836C | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66471278; called by muse, mutect2, varscan2
- KCNQ4 | c.1883C>A p.S628Y | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61272885, COSV61273186; called by muse, mutect2, varscan2
- KDM5D | c.934-1G>T p.X312_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | catalogued as COSV58736484; called by muse, mutect2, varscan2
- KIAA1210 | c.5044C>A p.P1682T | Missense Mutation (SNP) | VAF 138/276 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.546); catalogued as COSV68177282; called by muse, mutect2, varscan2
- KIF1B | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55809137; called by muse, mutect2
- KIF9 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV55519652; called by muse, mutect2, varscan2
- KIFAP3 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.265); catalogued as COSV63033993; called by muse, mutect2, varscan2
- KIRREL2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV52876627; called by muse, mutect2, varscan2
- KLHL24 | c.587A>T p.E196V | Missense Mutation (SNP) | VAF 219/466 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV54426288; called by muse, mutect2, varscan2
- KLHL28 | c.1037G>C p.G346A | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV61888198; called by muse, mutect2, varscan2
- LDLRAD2 | c.517T>G p.C173G | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV60828352; called by muse, mutect2, varscan2
- LEPROT | c.297C>A p.C99* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV60755455; called by muse, mutect2, varscan2
- LPAR4 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70912676, COSV70913335, COSV70913586; called by muse, mutect2, varscan2
- LRCH1 | c.940G>T p.V314L | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.08); catalogued as COSV60847534, COSV60853544; called by muse, mutect2, varscan2
- LY6G6C | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 202/360 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV65404400; called by muse, mutect2, varscan2
- LY75 | c.3236C>T p.S1079F | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV55105784; called by muse, mutect2, varscan2
- LYZL2 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV64684377; called by muse, mutect2, varscan2
- MAP1S | c.2776C>G p.R926G | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV60722772; called by muse, mutect2, varscan2
- MARK4 | c.1563G>T p.E521D | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53464138; called by muse, mutect2, varscan2
- MAST2 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs201146847, COSV63618347; called by muse, mutect2, varscan2
- MATK | c.1254C>G p.F418L (on ENST00000310132 / NM_139355.3; = p.F419L on NM_002378.4) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV59554635; called by muse, mutect2, varscan2
- MLKL | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58205172; called by muse, varscan2
- MRPS30 | c.304G>C p.A102P | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV72361351; called by muse, mutect2, varscan2
- MS4A14 | c.260C>A p.A87E | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55729897; called by muse, mutect2, varscan2
- MUC4 | c.15931G>C p.V5311L (on ENST00000463781 / NM_018406.7; = p.V1075L on NM_004532.6) | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.07); catalogued as rs1212623193, COSV57781135; called by muse, mutect2, varscan2
- MYH9 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 91/326 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV53386486; called by muse, mutect2, varscan2
- NAALADL2 | c.1037T>G p.M346R | Missense Mutation (SNP) | VAF 115/769 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.202); catalogued as COSV69156340; called by muse, mutect2, varscan2
- NAB2 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55666326; called by muse, mutect2
- NCAM2 | c.1239G>T p.W413C | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53066065, COSV53076020, COSV53108748; called by muse, mutect2, varscan2
- NCOA2 | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV51219524; called by muse, mutect2, varscan2
- NDC80 | c.582A>T p.I194= | Splice Region (SNP) | VAF 56/191 reads (29%) | catalogued as COSV55248095; called by muse, mutect2, varscan2
- NDST1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV55787408; called by muse, mutect2, varscan2
- NEMF | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.359); catalogued as COSV53591715; called by muse, mutect2, varscan2
- NIPBL | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56951689; called by muse, mutect2, varscan2
- NLRP5 | c.2270C>A p.P757H | Missense Mutation (SNP) | VAF 209/921 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV66762623; called by muse, mutect2, varscan2
- NSD1 | c.2919G>C p.Q973H | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV61776582; called by muse, mutect2, varscan2
- NUDT22 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 90/387 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV54173560; called by muse, mutect2, varscan2
- NXPE4 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV64943781; called by muse, mutect2, varscan2
- OR10G2 | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV73390370; called by muse, mutect2, varscan2
- OR10Q1 | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs926172190, COSV57470474; called by muse, mutect2, varscan2
- OR1D5 | c.505T>C p.C169R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV73859520; called by muse, mutect2, varscan2
- OR4K2 | c.897G>T p.R299S | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV53848607, COSV53849458; called by muse, mutect2
- OR52J3 | c.302C>A p.A101D | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1438900900, COSV66746954; called by muse, varscan2
- OR5AU1 | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as COSV58615591; called by muse, mutect2, varscan2
- OR5AU1 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV58615416; called by muse, mutect2, varscan2
- OR5B12 | c.461C>A p.A154E | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV56905072; called by muse, mutect2, varscan2
- OR5L2 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 116/471 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65724096; called by muse, mutect2, varscan2
- OR8U1 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 104/798 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs748897865, COSV100163694; called by muse, varscan2
- PACSIN2 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as COSV54319406, COSV54321806; called by muse, mutect2, varscan2
- PCDH17 | c.1035C>A p.N345K | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64974281, COSV64975234; called by muse, mutect2, varscan2
- PDE6A | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs764525413, COSV54927462; called by muse, mutect2, varscan2
- PEX1 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50395596, COSV50406081; called by muse, mutect2, varscan2
- PIFO | c.473T>A p.V158D | Missense Mutation (SNP) | VAF 76/352 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV63863862; called by muse, mutect2, varscan2
- PIK3C2G | c.3610G>T p.E1204* (on ENST00000676171; = p.E1163* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV56810072; called by muse, mutect2, varscan2
- PLAAT5 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 92/389 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV57137117; called by muse, mutect2, varscan2
- PLCL1 | c.1969C>A p.Q657K | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70833339; called by muse, mutect2, varscan2
- POC5 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs766216725, COSV100994403, COSV65973972; called by muse, mutect2, varscan2
- POTEF | c.400C>G p.H134D | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1270385869, COSV62541337; called by muse, mutect2, varscan2
- PRDM9 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs200386479, COSV57006661; called by muse, mutect2, varscan2
- PRODH2 | c.273del p.S92Pfs*7 (on ENST00000301175; = p.S16Pfs*7 on NM_021232.2 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/114 reads (15%) | catalogued as rs1224784313; called by mutect2, pindel, varscan2
- PRPF19 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV57127985; called by muse, mutect2, varscan2
- PRPF4 | c.482A>G p.Y161C (on ENST00000374198 / NM_001322267.2; = p.Y162C on NM_004697.5) | Missense Mutation (SNP) | VAF 118/389 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs770945831, COSV65252707; called by muse, mutect2, varscan2
- PSMD14 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1255835012, COSV68832516; called by muse, mutect2
- RBL2 | c.2329A>T p.I777F | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.024); catalogued as COSV50877798; called by muse, mutect2, varscan2
- RFC4 | c.817A>G p.K273E | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV56216952, COSV56217072; called by muse, mutect2, varscan2
- RGL2 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 144/299 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1419533755, COSV65842297; called by muse, mutect2, varscan2
- RGS7 | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0.052); catalogued as rs1338519941, COSV58542591; called by muse, mutect2, varscan2
- RHBDF2 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373646969; called by muse, mutect2, varscan2
- RIF1 | c.1806-1G>T p.X602_splice | Splice Site (SNP) | VAF 79/275 reads (29%) | catalogued as COSV54617313; called by muse, mutect2, varscan2
- RIMS1 | c.4501G>T p.G1501C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53456914; called by muse, mutect2, varscan2
- RIMS1 | c.4502G>T p.G1501V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53456925; called by muse, mutect2, varscan2
- RNASE2 | c.480C>G p.I160M | Missense Mutation (SNP) | VAF 109/455 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV58941233; called by muse, mutect2, varscan2
- RNF17 | c.788T>A p.I263N | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55040770; called by muse, mutect2, varscan2
- RPUSD2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.869); catalogued as COSV59765548; called by muse, mutect2, varscan2
- RYR2 | c.11218G>A p.V3740M | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100767080, COSV63686746; called by muse, mutect2, varscan2
- SCN1A | c.265-1G>T p.X89_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as CS072281, CS096237, COSV57670712, COSV57677485; called by muse, mutect2, varscan2
- SCN4A | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs1410143290, COSV71126979; called by muse, mutect2
- SCN8A | c.2498G>C p.S833T | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV61981993; called by muse, mutect2, varscan2
- SEMA5A | c.2690A>C p.E897A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV66793683; called by muse, mutect2, varscan2
- SERPINB6 | c.1137G>T p.Q379H (on ENST00000612421 / NM_001271823.2; = p.Q360H on NM_004568.6) | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV100177583, COSV59565834; called by muse, mutect2, varscan2
- SERPINB9 | c.328C>A p.Q110K | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66233464; called by muse, mutect2, varscan2
- SIPA1L3 | c.2507C>A p.T836N | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV55914494, COSV55917216; called by muse, mutect2, varscan2
- SLC27A5 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 76/350 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV54019725; called by muse, mutect2, varscan2
- SLC2A3 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 71/348 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50002908, COSV50004643; called by muse, mutect2, varscan2
- SLC4A8 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV60652084; called by muse, mutect2, varscan2
- SLCO1A2 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56602532; called by muse, varscan2
- SPAG16 | c.1138G>T p.G380C | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV59094597; called by muse, mutect2, varscan2
- SRPK1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1188396022, COSV60412906; called by muse, mutect2, varscan2
- SRRM4 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.937); catalogued as COSV57416789; called by muse, mutect2, varscan2
- SYCE1 | c.517T>A p.W173R (on ENST00000343131 / NM_001143764.3; = p.W137R on NM_130784.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV58217314; called by muse, mutect2
- SYNE1 | c.14755G>T p.D4919Y (on ENST00000367255 / NM_182961.4; = p.D4848Y on NM_033071.3) | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV54986777, COSV55075228; called by muse, mutect2, varscan2
- TAS2R19 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 62/392 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs1437011977, COSV66828432; called by muse, varscan2
- TAS2R3 | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV56092036; called by muse, mutect2, varscan2
- TBC1D22A | c.179C>G p.T60S | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV61439491; called by muse, mutect2, varscan2
- TEKT3 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.031); catalogued as rs753700946, COSV58627703, COSV58629495; called by muse, mutect2, varscan2
- TFAP2D | c.1073C>A p.P358Q | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50417194; called by muse, mutect2, varscan2
- THOC2 | c.3424C>G p.Q1142E | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV55546275; called by muse, mutect2, varscan2
- THSD4 | c.1249G>C p.V417L | Missense Mutation (SNP) | VAF 65/253 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.924); catalogued as COSV55970610; called by muse, mutect2, varscan2
- TMEM132E | c.772C>G p.R258G (on ENST00000321639; = p.R348G on NM_001304438.2) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.653); catalogued as rs79883914, COSV58697120; called by muse, mutect2, varscan2
- TMEM190 | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV52581817; called by muse, mutect2, varscan2
- TNC | c.1868-2A>G p.X623_splice | Splice Site (SNP) | VAF 45/124 reads (36%) | catalogued as COSV60785160; called by muse, mutect2, varscan2
- TOX | c.976G>C p.A326P | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63846226, COSV63849955; called by muse, mutect2, varscan2
- TRAPPC6A | c.332A>T p.Q111L (on ENST00000585934 / NM_001270891.2; = p.Q125L on NM_024108.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV50065213; called by muse, mutect2, varscan2
- TRPC4AP | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV52680096; called by muse, mutect2, varscan2
- TRPC6 | c.988G>T p.V330F | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60255000; called by muse, mutect2, varscan2
- TRPM5 | c.110G>C p.R37P | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV50153310, COSV50157216; called by muse, mutect2, varscan2
- TTN | c.9110A>G p.D3037G (on ENST00000591111; = p.D2991G on NM_003319.4) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | PolyPhen benign (0.046); catalogued as COSV60074884; called by muse, mutect2, varscan2
- TUBB4A | c.1243A>T p.M415L | Missense Mutation (SNP) | VAF 107/512 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV51155462; called by muse, mutect2, varscan2
- TYW1 | c.982A>T p.K328* | Nonsense Mutation (SNP) | VAF 78/306 reads (25%) | catalogued as COSV62752683; called by muse, mutect2, varscan2
- UBE3C | c.3030A>T p.K1010N | Missense Mutation (SNP) | VAF 99/347 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV61953340; called by muse, mutect2, varscan2
- UBR1 | c.2812A>G p.T938A | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1415080831, COSV51929903; called by muse, mutect2, varscan2
- USH2A | c.9316G>T p.V3106L | Missense Mutation (SNP) | VAF 75/300 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV56372407; called by muse, mutect2, varscan2
- VCL | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.403); catalogued as COSV53009520; called by muse, mutect2, varscan2
- VIPAS39 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV58939840; called by muse, mutect2, varscan2
- VWC2L | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV56970573, COSV56977486; called by muse, mutect2, varscan2
- WDCP | c.1006A>G p.I336V | Missense Mutation (SNP) | VAF 90/254 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as rs1451062482, COSV54592416; called by muse, mutect2, varscan2
- XKR7 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV73813191; called by muse, mutect2, varscan2
- XKR8 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV65834909; called by muse, mutect2, varscan2
- ZFYVE9 | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55094080; called by muse, mutect2, varscan2
- ZNF106 | c.1906A>T p.R636* | Nonsense Mutation (SNP) | VAF 128/421 reads (30%) | catalogued as COSV55516878; called by muse, mutect2, varscan2
- ZNF107 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs764145725, COSV61328789; called by muse, mutect2, varscan2
- ZNF25 | c.924C>G p.H308Q | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56922647; called by muse, mutect2, varscan2
- ZNF300 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as COSV51035492; called by muse, mutect2, varscan2
- ZNF384 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 82/617 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.909); catalogued as COSV60530533; called by muse, varscan2
- ZNF384 | c.204C>A p.D68E | Missense Mutation (SNP) | VAF 73/540 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as rs1178504242, COSV60530552; called by muse, varscan2
- ZNF446 | c.1061A>T p.H354L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV59991487; called by muse, mutect2, varscan2
- ZNF773 | c.1120C>G p.L374V | Missense Mutation (SNP) | VAF 128/628 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56588693; called by muse, mutect2, varscan2
- ZNF80 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 76/398 reads (19%) | catalogued as COSV57360874; called by muse, mutect2, varscan2
- ZNF804B | c.3151C>G p.Q1051E | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV60828780; called by muse, mutect2, varscan2
- ATP6V1B1 | c.119-7_121del p.X40_splice | Splice Site (DEL) | VAF 21/99 reads (21%) | called by mutect2, pindel, varscan2
- ATP6V1C1 | c.858_867del p.N286Kfs*9 | Frame Shift Del (DEL) | VAF 57/207 reads (28%) | called by mutect2, pindel, varscan2
- CDKL4 | c.411dup p.G138Rfs*7 | Frame Shift Ins (INS) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- CLEC6A | c.492del p.W164Cfs*3 | Frame Shift Del (DEL) | VAF 74/259 reads (29%) | called by mutect2, varscan2
- CREBBP | c.3605_3609+15del p.X1202_splice | Splice Site (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- FAM126B | c.1025_1032del p.V342Efs*2 | Frame Shift Del (DEL) | VAF 33/157 reads (21%) | called by mutect2, pindel, varscan2
- FILIP1 | c.3254_3260del p.G1085Vfs*9 | Frame Shift Del (DEL) | VAF 94/411 reads (23%) | called by mutect2, pindel, varscan2
- GUCY1B1 | c.1044del p.T349Rfs*32 | Frame Shift Del (DEL) | VAF 40/121 reads (33%) | called by mutect2, pindel, varscan2
- IGHV1-58 | c.178C>A p.R60S | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV1-6 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 73/417 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- IGKV2-30 | c.52T>A p.S18T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.048); called by mutect2, varscan2
- IGKV3-11 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF2B | c.1844dup p.S616Ifs*2 | Frame Shift Ins (INS) | VAF 109/314 reads (35%) | called by mutect2, pindel, varscan2
- MUC2 | c.3512G>T p.R1171M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- OR5M11 | c.745del p.L249Cfs*11 | Frame Shift Del (DEL) | VAF 35/183 reads (19%) | called by mutect2, pindel, varscan2
- PARP14 | c.4280_4290del p.A1427Gfs*4 | Frame Shift Del (DEL) | VAF 39/258 reads (15%) | called by mutect2, pindel, varscan2
- PPP1R3B | c.855_857del p.Y285del | In Frame Del (DEL) | VAF 17/98 reads (17%) | called by pindel, varscan2
- RFX7 | c.3723_3743del p.E1241_L1247del (on ENST00000559447 / NM_001368074.1; = p.E1338_L1344del on NM_022841.7 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 26/99 reads (26%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.3083G>T p.C1028F | Missense Mutation (SNP) | VAF 54/442 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.319); called by muse, mutect2
- STAP1 | c.712_719del p.I238Gfs*14 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- ACCSL | c.930G>C p.L310= | Silent (SNP) | VAF 51/238 reads (21%) | catalogued as COSV66581304; called by muse, mutect2, varscan2
- ADAT2 | c.210A>T p.R70= | Silent (SNP) | VAF 80/215 reads (37%) | catalogued as COSV52794435; called by muse, mutect2, varscan2
- AHNAK2 | c.15705C>T p.F5235= | Silent (SNP) | VAF 293/1578 reads (19%) | catalogued as rs1248246831, COSV60915817; called by muse, mutect2, varscan2
- ALG10 | c.96A>T p.R32= | Silent (SNP) | VAF 142/784 reads (18%) | catalogued as COSV56792699; called by muse, varscan2
- ANK2 | c.4359G>C p.P1453= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV52162156, COSV52162289; called by muse, mutect2, varscan2
- BAIAP2 | c.1521G>A p.A507= | Silent (SNP) | VAF 30/211 reads (14%) | catalogued as rs199796336; called by muse, mutect2, varscan2
- BCAN | c.777G>T p.L259= | Silent (SNP) | VAF 65/293 reads (22%) | catalogued as COSV61256954; called by muse, mutect2, varscan2
- BEND2 | c.1602C>A p.L534= | Silent (SNP) | VAF 212/478 reads (44%) | catalogued as COSV66215883; called by muse, mutect2, varscan2
- C4orf17 | c.672G>A p.E224= | Silent (SNP) | VAF 112/342 reads (33%) | catalogued as COSV58512498; called by muse, mutect2, varscan2
- CASR | c.2439C>T p.R813= (on ENST00000490131; = p.R890= on NM_000388.4) | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs1484810573, COSV56137617; called by muse, mutect2
- CCDC185 | c.1161G>C p.R387= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV64820920; called by muse, mutect2, varscan2
- CD248 | c.1557C>T p.T519= | Silent (SNP) | VAF 88/305 reads (29%) | catalogued as rs764716360, COSV60936539; called by muse, mutect2, varscan2
- CHL1 | c.9G>T p.P3= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs1044972919, COSV56593831; called by muse, mutect2, varscan2
- CHODL | c.696G>A p.L232= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as COSV54732767; called by muse, mutect2, varscan2
- CLEC4E | c.90C>T p.P30= | Silent (SNP) | VAF 188/580 reads (32%) | catalogued as COSV55225927; called by muse, mutect2, varscan2
- CMYA5 | c.3693A>T p.P1231= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV71406043; called by muse, mutect2, varscan2
- COL22A1 | c.921G>A p.K307= | Silent (SNP) | VAF 64/181 reads (35%) | catalogued as COSV57337696; called by muse, varscan2
- CWH43 | c.1974G>C p.V658= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as COSV56937454, COSV56939078; called by muse, mutect2, varscan2
- CYFIP2 | c.3738G>A p.L1246= (on ENST00000616178 / NM_001291722.2; = p.L1221= on NM_014376.4) | Silent (SNP) | VAF 45/227 reads (20%) | catalogued as COSV59038409; called by muse, mutect2, varscan2
- CYLC1 | c.858G>A p.K286= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV61412238; called by muse, mutect2, varscan2
- CYP27A1 | c.1575G>A p.Q525= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV51468309; called by muse, mutect2, varscan2
- CYP4F2 | c.60G>T p.L20= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV50001322; called by muse, mutect2, varscan2
- CYRIA | c.732G>A p.T244= | Silent (SNP) | VAF 57/308 reads (19%) | catalogued as rs375699408; called by muse, mutect2, varscan2
- DAAM2 | c.1446G>C p.T482= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV51321497; called by muse, mutect2
- DDX1 | c.2025G>T p.P675= | Silent (SNP) | VAF 85/299 reads (28%) | catalogued as rs762937956, COSV51840077, COSV99247010; called by muse, mutect2, varscan2
- DPT | c.127C>A p.R43= | Silent (SNP) | VAF 38/202 reads (19%) | catalogued as COSV63190010; called by muse, mutect2, varscan2
- DSP | c.1527G>T p.G509= | Silent (SNP) | VAF 128/256 reads (50%) | catalogued as rs397516917, COSV101131161; ClinVar: likely benign; called by mutect2, varscan2
- EFCAB1 | c.513A>G p.E171= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV50618374; called by muse, mutect2, varscan2
- ELANE | c.492G>A p.G164= | Silent (SNP) | VAF 50/243 reads (21%) | catalogued as COSV55048092; called by muse, mutect2, varscan2
- ERICH3 | c.3681G>C p.V1227= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as COSV58607090, COSV58607424; called by muse, mutect2, varscan2
- EZH1 | c.1434C>A p.I478= | Silent (SNP) | VAF 69/245 reads (28%) | catalogued as COSV70549483; called by muse, mutect2, varscan2
- F13B | c.1365T>C p.T455= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV66373929; called by muse, mutect2, varscan2
- FAT3 | c.11370A>T p.G3790= | Silent (SNP) | VAF 48/206 reads (23%) | catalogued as COSV53113087; called by muse, mutect2, varscan2
- FCRL3 | c.267C>G p.L89= | Silent (SNP) | VAF 52/379 reads (14%) | catalogued as COSV63841701; called by muse, mutect2, varscan2
- FEM1A | c.1800G>C p.L600= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as rs770305011, COSV54163916; called by muse, mutect2, varscan2
- FSTL4 | c.96G>T p.P32= | Silent (SNP) | VAF 67/208 reads (32%) | catalogued as COSV54771231; called by muse, mutect2, varscan2
- GCFC2 | c.1896A>G p.V632= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV58081120; called by muse, mutect2, varscan2
- GRM7 | c.1803G>A p.G601= | Silent (SNP) | VAF 114/268 reads (43%) | catalogued as COSV100738527, COSV63143857; called by muse, mutect2, varscan2
- IGKV2-30 | c.126C>A p.S42= | Silent (SNP) | VAF 33/208 reads (16%) | called by muse, mutect2, varscan2
- IL10RA | c.303G>T p.R101= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV57140672; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1611T>C p.I537= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV56262834; called by muse, mutect2, varscan2
- INPP5J | c.2148C>T p.Y716= (on ENST00000331075 / NM_001284285.2; = p.Y348= on NM_001002837.2) | Silent (SNP) | VAF 43/243 reads (18%) | catalogued as COSV58513160; called by muse, varscan2
- KCNH5 | c.2340T>C p.D780= | Silent (SNP) | VAF 61/185 reads (33%) | catalogued as COSV59760910; called by muse, mutect2, varscan2
- KCNK12 | c.991C>A p.R331= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV59945678; called by muse, varscan2
- KCNQ4 | c.1884C>T p.S628= | Silent (SNP) | VAF 56/238 reads (24%) | catalogued as COSV61273194; called by muse, mutect2, varscan2
- KIRREL2 | c.1167G>T p.A389= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs750790332, COSV52876614; called by muse, mutect2, varscan2
- LONRF2 | c.1794C>T p.D598= | Silent (SNP) | VAF 74/794 reads (9%) | catalogued as rs774083116, COSV66540656; called by muse, mutect2
- LRRC49 | c.685T>C p.L229= | Silent (SNP) | VAF 59/221 reads (27%) | catalogued as rs774182786, COSV53010960; called by muse, mutect2, varscan2
- LRRIQ4 | c.1053G>T p.L351= | Silent (SNP) | VAF 126/285 reads (44%) | catalogued as COSV61618656, COSV61619217; called by muse, mutect2, varscan2
- LRRTM1 | c.357G>T p.T119= | Silent (SNP) | VAF 67/326 reads (21%) | catalogued as COSV54438275, COSV54441429; called by muse, mutect2, varscan2
- LYZL2 | c.24C>T p.C8= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs1459689246, COSV64684382; called by muse, mutect2, varscan2
- MMP16 | c.1823G>A p.*608= | Silent (SNP) | VAF 64/213 reads (30%) | catalogued as COSV54150891, COSV54165758; called by muse, mutect2, varscan2
- MMP16 | c.6C>A p.I2= | Silent (SNP) | VAF 82/357 reads (23%) | catalogued as COSV54165771, COSV99689934; called by muse, mutect2, varscan2
- MRPL32 | c.555C>T p.F185= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV56239488; called by muse, mutect2, varscan2
- MYOM2 | c.1191C>T p.D397= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV50714225; called by muse, mutect2, varscan2
- MYORG | c.837G>C p.L279= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV52626998, COSV52627229; called by muse, mutect2, varscan2
- NAPSA | c.306C>G p.L102= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV53797530; called by muse, mutect2
- NLRP7 | c.1446G>A p.L482= | Silent (SNP) | VAF 46/230 reads (20%) | catalogued as COSV60174999; called by muse, mutect2, varscan2
- NPHS2 | c.1143C>A p.P381= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as CD1512222, COSV62635324; called by muse, mutect2, varscan2
- NRXN1 | c.1230T>A p.S410= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV58454074; called by muse, mutect2, varscan2
- OR4K5 | c.888T>A p.A296= | Silent (SNP) | VAF 34/394 reads (9%) | catalogued as COSV60003595; called by muse, mutect2
- PDGFRA | c.123G>C p.L41= | Silent (SNP) | VAF 92/320 reads (29%) | catalogued as COSV57268202; called by muse, mutect2, varscan2
- POMT2 | c.1734C>T p.R578= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV55071280; called by muse, mutect2, varscan2
- PZP | c.4206A>G p.V1402= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as COSV54360916; called by muse, mutect2, varscan2
- RADIL | c.180G>T p.S60= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs779865431, COSV101271437, COSV68200910; called by muse, mutect2, varscan2
- RECQL4 | c.3342G>A p.Q1114= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56739466, COSV56741084; called by muse, mutect2, varscan2
- RERE | c.1194G>A p.E398= | Silent (SNP) | VAF 31/153 reads (20%) | catalogued as COSV61942505; called by muse, mutect2, varscan2
- RIOK2 | c.183C>G p.L61= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV51612877; called by muse, mutect2, varscan2
- RP1 | c.5442A>T p.L1814= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV55117164; called by muse, mutect2, varscan2
- SERTM1 | c.189C>T p.L63= | Silent (SNP) | VAF 118/409 reads (29%) | catalogued as COSV59376555; called by muse, mutect2, varscan2
- SKIV2L | c.3126C>T p.F1042= | Silent (SNP) | VAF 71/299 reads (24%) | catalogued as rs774425049, COSV61713700; called by muse, mutect2, varscan2
- SLC6A5 | c.1671G>T p.L557= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as rs1565284979, COSV54226898; called by muse, mutect2, varscan2
- SNX8 | c.1104C>G p.S368= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV56127023; called by muse, mutect2, varscan2
- TET1 | c.5385T>G p.P1795= | Silent (SNP) | VAF 57/185 reads (31%) | catalogued as COSV65384897; called by muse, mutect2, varscan2
- TRPM3 | c.1323T>C p.D441= (on ENST00000357533 / NM_001366142.2; = p.D286= on NM_020952.6) | Silent (SNP) | VAF 42/202 reads (21%) | catalogued as COSV62586220; called by muse, mutect2, varscan2
- UGT2B4 | c.1074C>A p.P358= | Silent (SNP) | VAF 36/278 reads (13%) | catalogued as COSV59317434; called by muse, mutect2, varscan2
- VASH2 | c.912C>A p.T304= (on ENST00000517399 / NM_001301056.2; = p.T260= on NM_024749.5) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV55117853; called by muse, mutect2, varscan2
- VPS51 | c.741C>T p.G247= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1209698789, COSV54207402; called by muse, mutect2, varscan2
- VPS8 | c.1236A>T p.S412= (on ENST00000625842 / NM_001349294.1; = p.S410= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/351 reads (15%) | catalogued as COSV54986178; called by muse, mutect2, varscan2
- WNK1 | c.4830G>T p.V1610= (on ENST00000315939 / NM_018979.4; = p.V1363= on NM_014823.3) | Silent (SNP) | VAF 148/437 reads (34%) | catalogued as COSV60033749; called by muse, mutect2, varscan2
- BTN2A3P | n.83A>T | RNA (SNP) | VAF 89/148 reads (60%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+2609C>A | Intron (SNP) | VAF 94/362 reads (26%) | catalogued as rs761642597, COSV100638858, COSV59107346; called by muse, mutect2, varscan2
- MIR1283-1 | n.61T>A | RNA (SNP) | VAF 53/189 reads (28%) | called by muse, mutect2, varscan2
- NRP1 | c.981+4520A>G | Intron (SNP) | VAF 14/53 reads (26%) | catalogued as rs920648654; called by muse, mutect2, varscan2
- RPL27A | c.319-174C>G | Intron (SNP) | VAF 62/192 reads (32%) | catalogued as COSV100029838; called by muse, mutect2, varscan2
- SKA2 | c.33+103G>A | Intron (SNP) | VAF 126/263 reads (48%) | catalogued as COSV99231260; called by muse, mutect2, varscan2
- SPAG11B | c.*42T>A | 3'UTR (SNP) | VAF 45/419 reads (11%) | catalogued as COSV99872669; called by muse, mutect2, varscan2
